Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9OT, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9OT-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Anterior prostatic fat, biopsy: Benign fibrofatty tissue, no carcinoma.
- B. Prostate and seminal vesicles, total prostatectomy:**
1. Prostatic adenocarcinoma, Gleason score 3+3 = 6, involving right and left lobes; see comment.
2. Seminal vesicles with no significant pathologic abnormality.

COMMENT:

Synoptic Comment for Prostate Tumors

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate C61.9
9/23/27/14

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left posterior mid gland (slides B6, B16, B17 and B18), right posterior mid gland (slides B11-B14 and B25).
- **Estimated volume of tumor:** 4.2 cc.
- **Gleason score:** 3+3; primary pattern 3, secondary pattern 3.
- **Estimated volume > Gleason pattern 3:** <1%.
- **Involvement of capsule:** Tumor invades capsule (B11, B12, B13, B14).
- **Extraprostatic extension:** None.
- **Margin status for tumor:**
- Positive (slide B14); length of positive margin 0.3 cm at black inked posterior margin on slide B14. Gleason pattern at largest positive margin is 3+3=6.
- **Margin status for benign prostate glands:**
- No benign glands present at inked excision margins.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present, focally.
- **Tumor involvement of seminal vesicle:** None.
- **Perineural infiltration:** Present.
- **Lymph node status:** None present.
- **AJCC/UICC stage:** pT2cNx.

Level sections on blocks B12, B13, B17 and B18 were evaluated and confirm the diagnosis.

[page 2 of 3]
Specimen(s) Received

A: Anterior prostatic fat

B: Prostate gland + seminal vesicles (fresh)

Clinical History

The patient is a [REDACTED] year-old man who, per review of the electronic medical record [REDACTED] was diagnosed with Gleason score $3 + 3 = 6$ prostatic adenocarcinoma of the right mid-gland and base with perineural invasion [REDACTED]. He now undergoes a robot-assisted radical prostatectomy.

Gross Description

The specimen is received in two parts, each labeled with the patient's name and medical record number. Part A is received in formalin. Part B is received fresh.

Part A, labeled "anterior prostatic fat," consists of multiple soft, irregular pieces of yellow, fibrofatty tissue (4.4 x 2.9 x 1.2 cm in aggregate). No masses or candidate lymph nodes are found. The specimen is entirely submitted in cassette A1.

Part B, labeled "prostate gland and seminal vesicles," consists of a radical prostatectomy specimen (76 gm; 4 cm from apex to base x 5 cm in width x 4 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: There are two nodules. Nodule 1 (1.5 x 1.2 x 0.6 cm) is ill defined, rubbery and yellow. It is located in the right posterior gland (slices 4-10) and abuts the posterior margin. Nodule 2 (0.8 x 0.4 x 0.3 cm) is ill defined, rubbery and yellow. It is located in the left posterior gland (slices 5-7) and is 0.3 cm from the posterior margin. The anterior fibrous stroma is red, roughened and is open. The remaining capsule is intact. The remaining prostatic parenchyma is tan. The seminal vesicle/vas deferens bundles (right 3 x 2.5 x 0.5 cm; left 3 x 2 x 0.5 cm) are soft, lobulated and without obvious lesion or mass. Some of the prostate is taken by the

ORIENTED BY: Anatomic landmarks.

INKING:

- Right anterior: Green.
- Left anterior: Blue.
- Posterior: Black.

GROSS PHOTOGRAPHS: Yes.

TOTAL NUMBER OF SLICES: 9; not including apex and base margin slices.

AVERAGE SLICE THICKNESS: 0.4 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

B1: Right apex.

B2: Left apex.

Additional tissue

B3: Right half, slice 1.

B4: Left half, slice 1.

B5: Right half, slice 2.

B6: Left half, slice 2.

Right anterior quadrant

B7: Slice 4.

B8: Slice 5.

B9: Slice 6.

B10: Slice 7.

Right posterior quadrant

B11: Slice 4 (suspicious nodule 1).

[page 3 of 3]
B12: Slice 5 (suspicious nodule 1).
B13: Slice 6 (suspicious nodule 1).
B14: Slice 7 (suspicious nodule 1).
Left posterior quadrant
B15: Slice 4.
B16: Slice 5 (suspicious nodule 2).
B17: Slice 6 (suspicious nodule 2).
B18: Slice 7 (suspicious nodule 2).
Left anterior quadrant
B19: Slice 4.
B20: Slice 5.
B21: Slice 6.
B22: Slice 7.
Bladder margins, entirely submitted in perpendicular sections
B23: Right.
B24: Left.
Prostatic/seminal vesicle junction and cross-section of vas deferens
B25: Right.
B26: Left.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed

Source: NCI Genomic Data Commons file 93cd85b8-9164-4b1f-adbd-02d6d4976383 (TCGA-V1-A9OT.40B928AE-1977-4077-9F44-282E85273EF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).